Somatic mutation profile of tumor specimen MP2PRT-PAPAXH-TMP1-A (aliquot MP2PRT-PAPAXH-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPAXH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (983 days).
Specimen MP2PRT-PAPAXH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccfe41ea-f28e-464c-911f-99603dbd8c78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPAXH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPAXH-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1af5840-e438-41b2-bea8-a72b2d7c27fb

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, RNA 1, In Frame Ins 1, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 31/452 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ASPM | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs540157512; called by muse, mutect2
- ATP10D | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 190/462 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146146861; called by muse, mutect2, varscan2
- ATP2B3 | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 70/786 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs368530977, COSV54840353; called by muse, mutect2
- AVEN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 94/217 reads (43%) | catalogued as rs766300982, COSV60734025; called by muse, varscan2
- FLT3 | c.1739A>C p.Q580P | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV54044827; called by muse, mutect2
- SPACA3 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 182/414 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52191162; called by muse, mutect2, varscan2
- GRM7 | c.1420C>G p.P474A | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.245); called by muse, mutect2
- HECTD1 | c.746_747insGGAAAG p.G249_P250insER | In Frame Ins (INS) | VAF 153/417 reads (37%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PXDNL | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 149/357 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2A3 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF600 | c.1469_1470insGG p.I491Efs*20 | Frame Shift Ins (INS) | VAF 139/355 reads (39%) | called by mutect2, pindel, varscan2
- FAT1 | c.9147C>T p.D3049= | Silent (SNP) | VAF 93/235 reads (40%) | catalogued as rs747040724, COSV71673153; called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insC p.*117A | Silent (INS) | VAF 93/246 reads (38%) | called by mutect2, pindel, varscan2
- OR1N1 | c.732C>T p.C244= | Silent (SNP) | VAF 174/440 reads (40%) | catalogued as rs372806915; called by muse, mutect2, varscan2
- SLC6A17 | c.2145C>T p.S715= | Silent (SNP) | VAF 117/292 reads (40%) | catalogued as rs151260028; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRD4 | c.2158+563G>T | Intron (SNP) | VAF 64/919 reads (7%) | called by muse, mutect2
- REXO1L1P | n.1484C>A | RNA (SNP) | VAF 122/1669 reads (7%) | called by muse, mutect2
